Surgical pathology report (de-identified scan), TCGA case TCGA-55-5899, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-5899-01A (Primary Tumor).

[page 1 of 2]
FINAL PATHOLOGIC DIAGNOSIS:

Lung, right upper lobe, biopsies:

Adenocarcinoma - see comment.

COMMENTS:

Histologic sections show an invasive carcinoma consisting primarily of sheets of cells with scattered, discrete glandular structures. The neoplastic cells have prominent nucleoli, and do not have the cytologic appearance of small cell carcinoma, grade II neuroendocrine carcinoma (atypical carcinoid) or large cell neuroendocrine carcinoma.

Immunohistochemical stains are performed. The neoplasm stains positively for cytokeratin CK7 as well as for TTF-1.

The neoplasm is negative for CK20, high molecular weight keratin SK and p63. The findings support the diagnosis of adenocarcinoma of lung primary. There is weak staining for synaptophysin. It is felt in that this is an example of non-neuroendocrine carcinoma (adenocarcinoma) that shows positive staining for synaptophysin, and that it should not result in classification of a neuroendocrine tumor.

Current NCCN practice guidelines recommend determination of EGFR and KRAS mutation status in adenocarcinoma of lung to help select patients for Tyrosine-Kinase Inhibitor (TKI) therapy. EGFR-activating mutations have been shown to be significantly associated with response to TKIs and KRAS mutations are associated with TKI resistance. They are mutually exclusive in NSCLC. Additionally, recent data show that ALK (Anaplastic Lymphoma Kinase) gene rearrangements in adenocarcinoma of lung are associated with resistance to TKIs and have favorable response rates to Crizotinib, the ALK inhibitor agent currently in clinical trials. Mutation analysis for KRAS and EGFR-TK domain and ALK gene rearrangement by FISH is available as the Lung Cancer Mutation Panel. Testing may be performed on paraffin-embedded tissue from the primary or metastatic tumor or pleural fluid cell block. These tests are available on request as a panel or as individual assays.

This case has been reviewed by
who agree with the diagnosis.

[page 2 of 2]
FINAL PATHOLOGIC DIAGNOSIS:

Bronchus, right, washing:

Negative for malignant cells.

Respiratory epithelial cells, squamous cells and macrophages are present.

COMMENTS:

CLINICAL HISTORY:

The patient is a with a right upper lobe lung mass.

CODES:

88112

GROSS DESCRIPTION:

A. A liquid based preparation is reviewed that has been prepared from 7 mls of bloody red fluid submitted as bronchial washing.

Source: NCI Genomic Data Commons file e107b11d-8343-4cfc-847d-12656ca0df2f (TCGA-55-5899.8FCDC599-A63E-4774-A58D-8B1B19D13980.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).